Somatic mutation profile of tumor specimen ALCH-B74K-TTP1-A (aliquot ALCH-B74K-TTP1-A-1-0-D-A95Q-47) from ALCHEMIST case ALCH-B74K, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 74.0 years (27,032 days).
Specimen ALCH-B74K-TTP1-A: Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b286246e-6593-4ca4-b96c-2ca974979a94.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B74K-NB1-A (Peripheral Whole Blood; tissue type Normal), aliquot ALCH-B74K-NB1-A-1-0-D-A95Q-47; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/838ab234-0c8d-4c0a-ae82-f4f4fb7cd089

The open-access MAF lists 42 somatic variants for this specimen: 30 protein-altering or splice-affecting, 8 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 24, Silent 8, Nonsense Mutation 4, Frame Shift Del 2, Intron 2, 5'UTR 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- RPL5 | c.244G>T p.E82* | Nonsense Mutation (SNP) | VAF 14/192 reads (7%) | catalogued as rs587777117, CM1313012, COSV59872943; ClinVar: pathogenic; called by muse, mutect2
- ADAMTS12 | c.1336C>T p.R446* | Nonsense Mutation (SNP) | VAF 25/100 reads (25%) | catalogued as rs368561249; called by muse, mutect2, varscan2
- GAS6 | c.1584del p.D529Tfs*12 | Frame Shift Del (DEL) | VAF 3/21 reads (14%) | catalogued as COSV100581491; called by pindel, varscan2
- HCN4 | c.1759C>T p.R587W | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as rs767228162, COSV99984286; called by mutect2, varscan2
- LUC7L2 | c.623A>T p.D208V | Missense Mutation (SNP) | VAF 26/242 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54923460; called by muse, mutect2, varscan2
- NFATC3 | c.2953G>A p.G985S | Missense Mutation (SNP) | VAF 14/206 reads (7%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.382); catalogued as rs564615486; called by muse, mutect2
- PRSS33 | c.637G>A p.G213R | Missense Mutation (SNP) | VAF 3/25 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.042); catalogued as rs1340619736; called by muse, varscan2
- RPS3A | c.277G>T p.G93C | Missense Mutation (SNP) | VAF 25/257 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1361512293; called by muse, mutect2
- SYNE1 | c.17898G>T p.Q5966H (on ENST00000367255 / NM_182961.4; = p.Q5895H on NM_033071.3) | Missense Mutation (SNP) | VAF 7/180 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); catalogued as COSV99555713; called by muse, mutect2
- TCIRG1 | c.1076C>T p.P359L | Missense Mutation (SNP) | VAF 3/21 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1436902507; called by muse, varscan2
- ZFP69 | c.654G>C p.K218N | Missense Mutation (SNP) | VAF 17/215 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs1426588525; called by muse, mutect2
- ADAMTS4 | c.2338C>A p.P780T | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.707); called by muse, mutect2, varscan2
- ANK3 | c.20A>T p.Q7L | Missense Mutation (SNP) | VAF 15/195 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.932); called by muse, mutect2
- C2orf69 | c.826G>A p.E276K | Missense Mutation (SNP) | VAF 13/323 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- DNAH14 | c.871A>G p.T291A (on ENST00000445597; = p.T164A on NM_144989.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 19/179 reads (11%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- DYNC1I2 | c.421G>A p.A141T | Missense Mutation (SNP) | VAF 12/206 reads (6%) | SIFT tolerated (0.73); PolyPhen benign (0.013); called by muse, mutect2
- INTS14 | c.1160G>C p.S387T (on ENST00000313182 / NM_001366360.2; = p.S308T on NM_001136043.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 18/206 reads (9%) | SIFT tolerated (0.58); PolyPhen benign (0.012); called by muse, mutect2
- IQSEC3 | c.1303C>T p.Q435* (on ENST00000538872 / NM_001170738.2; = p.Q132* on NM_015232.1) | Nonsense Mutation (SNP) | VAF 3/19 reads (16%) | called by muse, varscan2
- KLHL9 | c.555G>C p.L185F | Missense Mutation (SNP) | VAF 17/285 reads (6%) | SIFT deleterious (0.05); PolyPhen benign (0.392); called by muse, mutect2
- MICALL1 | c.2087A>G p.D696G | Missense Mutation (SNP) | VAF 3/26 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, varscan2
- MUC16 | c.13514C>G p.T4505S | Missense Mutation (SNP) | VAF 27/149 reads (18%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- MYH2 | c.3398C>T p.A1133V | Missense Mutation (SNP) | VAF 10/155 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.151); called by muse, mutect2
- NOX5 | c.53C>T p.T18I | Missense Mutation (SNP) | VAF 5/60 reads (8%) | SIFT tolerated (0.29); PolyPhen benign (0.001); called by muse, mutect2
- PSG5 | c.234C>A p.Y78* | Nonsense Mutation (SNP) | VAF 25/274 reads (9%) | called by muse, mutect2
- RNASEL | c.886G>A p.G296R | Missense Mutation (SNP) | VAF 10/180 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SLC6A7 | c.1267_1273del p.K423Cfs*12 | Frame Shift Del (DEL) | VAF 10/67 reads (15%) | called by mutect2, pindel, varscan2
- TMEM230 | c.272T>C p.L91P | Missense Mutation (SNP) | VAF 17/110 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- TRIM51 | c.1311_1322delinsTTGGTTGTGGGG p.S438_P441delinsWLWG | Missense Mutation (ONP) | VAF 10/113 reads (9%) | called by mutect2*, pindel
- ZNF469 | c.3904C>T p.P1302S (on ENST00000437464; = p.P1330S on NM_001367624.2) | Missense Mutation (SNP) | VAF 3/31 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.779); called by muse, mutect2, varscan2
- ZNF654 | c.3157C>T p.P1053S | Missense Mutation (SNP) | VAF 28/326 reads (9%) | SIFT tolerated (0.38); PolyPhen probably damaging (0.999); called by muse, mutect2
- FAM47B | c.351C>T p.F117= | Silent (SNP) | VAF 16/174 reads (9%) | catalogued as rs1483087036, COSV61455447; called by muse, mutect2
- GAN | c.117G>A p.E39= | Silent (SNP) | VAF 4/25 reads (16%) | called by muse, mutect2, varscan2
- H3-5 | c.69G>A p.T23= | Silent (SNP) | VAF 15/73 reads (21%) | catalogued as rs148428845; called by muse, mutect2, varscan2
- KLHL9 | c.954G>C p.R318= | Silent (SNP) | VAF 18/175 reads (10%) | called by muse, mutect2
- MMAA | c.1191C>T p.L397= | Silent (SNP) | VAF 34/258 reads (13%) | called by muse, mutect2, varscan2
- MMP24 | c.927G>A p.T309= | Silent (SNP) | VAF 6/39 reads (15%) | catalogued as rs757349694, COSV55770930; called by muse, mutect2, varscan2
- SLC13A1 | c.1092A>C p.R364= | Silent (SNP) | VAF 27/269 reads (10%) | called by muse, mutect2
- TTC28 | c.5100G>A p.S1700= | Silent (SNP) | VAF 4/29 reads (14%) | catalogued as rs1240048876; called by muse, mutect2, varscan2
- ARMCX4 | c.1038+1767G>T | Intron (SNP) | VAF 5/98 reads (5%) | called by muse, mutect2
- ARMCX4 | c.1038+1768G>T | Intron (SNP) | VAF 5/96 reads (5%) | called by muse, mutect2
- CCNJL | c.-67del | 5'UTR (DEL) | VAF 3/19 reads (16%) | catalogued as rs998820063; called by pindel, varscan2
- FOXO3B | chr17:18662888 G>C | 3'Flank (SNP) | VAF 18/228 reads (8%) | called by muse, mutect2
